Gene-level copy-number profile of tumor specimen TCGA-44-A479-01A from TCGA case TCGA-44-A479, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 74.0 years (27,024 days).
Specimen TCGA-44-A479-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.bf4b1160-f9a5-4bbf-aaf8-508674fe795a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-A479-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d42d597e-75f1-4327-b400-492882bca8e0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,204; copy number 2: 9,442; copy number 3: 19,177; copy number 4: 20,594; copy number 5: 6,384; copy number 6: 2,334; copy number 7: 417; copy number 8: 65; copy number 10: 183; copy number 12: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-A479-01A-31D-A24C-01): tumor purity 0.36, ploidy 2.14, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 685 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:73,297,711–78,558,503, 65 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr12:24,566,964–25,250,936, 20 genes, copy number 12: LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2.
- chr14:29,390,074–49,852,821, 286 genes, copy number 7–10 (within-gene range 5–10) (broad region; genes not listed).
- chr20:50,999,370–64,313,132, 314 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,204. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
